Gene-level copy-number profile of tumor specimen TCGA-3H-AB3S-01A from TCGA case TCGA-3H-AB3S, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 69.7 years (25,471 days).
Specimen TCGA-3H-AB3S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.0e45783d-8c43-4b1d-9f05-c4a439b6ea9a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3H-AB3S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a99d4ff5-4564-409e-8c63-b5265ae185ae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 149; copy number 1: 8,827; copy number 2: 48,587; copy number 3: 2,256.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3H-AB3S-01A-21D-A39Q-01): tumor purity 0.81, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 144 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:246,682,108–246,691,821, 2 genes: AL591848.2, AL591848.1.
- chr5:157,341,596–157,460,100, 1 gene (within-gene range 0–2): AC008676.3.
- chr5:157,395,534–157,690,878, 9 genes: ADAM19, AC008676.2, NIPAL4, AC106801.1, RNU6-390P, AC008694.2, SOX30, C5orf52, AC008694.1.
- chr8:41,566,858–41,568,641, 1 gene: AC009630.4.
- chr9:19,926,094–28,888,955, 125 genes (broad region; genes not listed).
- chr14:20,684,177–20,735,011, 6 genes (within-gene range 0–1): ANG, RNASE4, AL163636.1, EGILA, RANBP20P, EDDM3DP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,411. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
